Surgical pathology report (de-identified scan), TCGA case TCGA-96-A4JL, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Washington University - NYU, specimen TCGA-96-A4JL-01A (Primary Tumor).

[page 1 of 4]
9/21/12

SURGICAL PATHOLOGY REPORT

COLLECTION DATE:

SPECIMENS:

1. STATION 9 LYMPH NODE
2. STATION 7 LYMPH NODE
3. STATION 10 LYMPH NODE
4. STATION 12 LYMPH NODE
5. STATION 11 LYMPH NODE
6. STATION 5 LYMPH NODE
7. LUNG, LEFT LOWER LOBECTOMY

1C8-4-3

carcinoma, squamous cell, NOS 8070/3

Site: lung, lower lobe c34.3

hw
10/2/12

DIAGNOSIS:

1. LYMPH NODE, LEVEL 9: Biopsy

- One lymph node, negative for carcinoma (0/1).

2. lymph node, LEVEL 7: Biopsy

- One lymph node, negative for carcinoma (0/1).

3. lymph node, LEVEL 10: Biopsy

- FOUR lymph nodeS, negative for carcinoma (0/4).

4. lymph node, LEVEL 12: Biopsy

- metastatic carcinoma INVOLVING THREE OF FIVE LYMPH NODES (3/5).

5. lymph node, LEVEL 11: Biopsy

- metastatic carcinoma INVOLVING THREE OF FOUR LYMPH NODES (3/4).

6. lymph node, LEVEL 5: Biopsy

- One lymph node, negative for carcinoma (0/1).

7. Lung, left lower LOBE: lobectomy

- squamous CELL carcinoma, poorly differentiated (2.8 CM), WITH VISCERAL PLEURAL INVASION (SEE NOTE).

[page 2 of 4]
- the BRONCHIAL AND VASCULAR MARGINS ARE FREE OF TUMOR.
- THREE LYMPH NODES, NEGATIVE FOR CARCINOMA (0/3).

Note: Immunohistochemical stains show that the tumor cells are positive for p63 and CK5/6 while negative for CK7, CK20 and TTF-1, supporting the diagnosis. Visceral pleural invasion is identified on an elastic stain on block 7C.

Specimens: 1: STATION 9 LYMPH NODE
2: STATION 7 LYMPH NODE
3: STATION 10 LYMPH NODE
4: STATION 12 LYMPH NODE
5: STATION 11 LYMPH NODE
6: STATION 5 LYMPH NODE
7: LUNG, LEFT LOWER LOBECTOMY

**LUNG: Resection
SPECIMEN**

Specimen: Lobe(s) of lung (specify)

Left lower

Procedure: Lobectomy

Specimen Laterality: Left

Tumor Site: Lower lobe

Tumor Focality: Unifocal

TUMOR

Histologic Type: Squamous cell carcinoma

Histologic Grade: G3: Poorly differentiated

EXTENT

Tumor Size: Greatest dimension (cm)

2.8cm

Visceral Pleura Invasion: Present

MARGINS

Bronchial Margin

Bronchial Margin Involvement by Invasive Carcinoma:

Uninvolved by invasive carcinoma

Bronchial Margin Involvement by Squamous Cell Carcinoma in situ

(CIS):

Squamous cell carcinoma in situ (CIS) not identified at bronchial margin

Vascular Margin: Uninvolved by invasive carcinoma

ACCESSORY FINDINGS

Lymph-Vascular Invasion: Present

LYMPH NODES

Extranodal Extension: Not identified

STAGE (pTNM)

TNM Descriptors: Not applicable

Primary Tumor (pT):

[page 3 of 4]
pT2a: Tumor greater than 3 cm, but 5 cm or less in greatest dimension surrounded by lung or visceral pleura without bronchoscopic evidence of invasion more proximal than the lobar bronchus (i.e., not in the main bronchus); or Tumor 5 cm or less in greatest dimension with any of the following features of extent: involves main bronchus, 2 cm or more distal to the carina; invades the visceral pleura; associated with atelectasis or obstructive pneumonitis that extends to the hilar region but does not involve the entire lung

Regional Lymph Nodes (pN)

pN1: Metastasis in ipsilateral peribronchial and / or ipsilateral hilar lymph nodes, and intrapulmonary nodes including involvement by direct extension

Distant Metastases (pM): Not applicable

Pathologist

CLINICAL HISTORY AND PRE - OPERATIVE DIAGNOSIS:

F with a 2.3 cm LLL squamous cell carcinoma.

MACROSCOPIC DESCRIPTION:

1. The specimen is received in saline labeled "STATION 9 LYMPH NODES" and consists of one lymph node measuring 0.8 x 0.7 x 0.5 cm. Entirely submitted one cassette.

2. The specimen is received in saline labeled "STATION SEVEN LYMPH NODES" and consists of one lymph node measuring 1 x 0.8 x 0.5 cm. Entirely submitted in one cassette.

3. The specimen received in saline labeled "STATION 10 LYMPH NODES" and consists of four anthracotic lymph nodes measuring from 0.5 up to 0.7 cm in greatest dimension. Entirely submitted in one cassette

4. The specimen is received in saline labeled "STATION 12 LYMPH NODES" and consists of five anthracotic lymph nodes measuring from 0.4 up to one cm in greatest dimension. Entirely submitted in one cassette

5. The specimen is received in saline labeled "STATION 11 LYMPH NODES" and consists of four fragmented anthracotic lymph nodes measuring from 0.6 up to one cm in greatest dimension. Entirely submitted in one cassette.

6. The specimen is received in saline labeled "STATION FIVE LYMPH NODES" and consists off one anthracotic lymph node measuring 1 x 0.8 x 0.5 cm. Entirely submitted in one cassette.

[page 4 of 4]
7. The specimen is received fresh labeled "LEFT LOWER LOBECTOMY" and consists of a lower lobe of the lung measuring 17 x 9.5 x 3.5 cm. The staple line measures 11 cm which is shaved and the parenchyma inked blue. Bronchial margin measures two cm and vascular margin measure 1.2 cm at the hilum. The pleura is grey-pink glistening and reveals a puckered area measuring 1.5 cm in greatest dimension which is inked black. Beneath the puckered pleura there is a grey-white firm mass measuring 2.8 x 2.5 x 2 cm. The mass located at the lower mediastinal surface of the lobe, five cm from the staple line and four cm from the hilar structures. The remainder of the parenchyma is pink-red blotchy and crepitant. No other nodules grossly identified. Representative sections are submitted as follows.

SUMMARY OF SECTIONS:

1A in toto
2A in toto
3A in toto
4A in toto
5A in toto
6A in toto
7A-7C mass
7D- bronchial margin, shave
7E- vascular margin, shave
7F staple line margin
7G-7H random section of lung

Final Diagnosis performed by

Electronically signed

The electronic signature attests that the named Attending Pathologist has evaluated the specimen referred to in the signed section of the report and formulated the diagnosis therein.

This report may include one or more immunohistochemical stain results that use analyte specific reagents.
The tests were developed and their performance characteristics determined by

They have not been cleared or approved by the US Food and Drug Administration.
The FDA has determined that such clearance or approval is not necessary.

Source: NCI Genomic Data Commons file 6e7ad085-0953-4d9c-8df7-cef333c7b2f1 (TCGA-96-A4JL.7004E0F3-E9C5-4CF4-99ED-25C8401CBC87.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).